Somatic mutation profile of tumor specimen MP2PRT-PARIZL-TMP1-A (aliquot MP2PRT-PARIZL-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARIZL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,038 days).
Specimen MP2PRT-PARIZL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 687367c7-b425-42a5-a5bb-1aa0cac7daf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARIZL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARIZL-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7216bef3-83d0-4c1e-b7d4-cd6043caa341

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY1 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1490066336, COSV52030543; called by muse, mutect2, varscan2
- ALX4 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 34/656 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs751290539, COSV61329210; called by muse, mutect2
- CILP2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 45/316 reads (14%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV52273437; called by muse, mutect2, varscan2
- GLRA2 | c.47T>C p.F16S | Missense Mutation (SNP) | VAF 36/470 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV54345881; called by muse, mutect2
- GRIP2 | c.3247G>A p.D1083N (on ENST00000619221; = p.D986N on NM_001080423.4) | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1377785050; called by muse, mutect2
- SHROOM3 | c.3094G>A p.V1032M | Missense Mutation (SNP) | VAF 114/567 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs151102508; called by muse, mutect2, varscan2
- TRPM8 | c.153A>T p.K51N | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61222949; called by muse, mutect2
- ADIPOR2 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHST9 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- MAGED1 | c.703G>C p.A235P | Missense Mutation (SNP) | VAF 27/605 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2
- CLCNKB | c.1452G>A p.T484= | Silent (SNP) | VAF 55/356 reads (15%) | catalogued as rs777631984, COSV65162471; called by muse, mutect2, varscan2
- SVEP1 | c.9378G>A p.P3126= | Silent (SNP) | VAF 39/330 reads (12%) | catalogued as rs760674753, COSV52839020; called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins CCTCGACA | 3'Flank (INS) | VAF 14/71 reads (20%) | called by mutect2, pindel*, varscan2
- OSBPL6 | c.987+4542C>T | Intron (SNP) | VAF 33/261 reads (13%) | catalogued as rs376557013; called by muse, mutect2, varscan2
